Somatic mutation profile of tumor specimen HCM-CSHL-0818-C56-06A (aliquot HCM-CSHL-0818-C56-06A-11D-A881-36) from HCMI case HCM-CSHL-0818-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIC; FIGO stage: Stage IIIC; Tumor grade: High Grade; Age at diagnosis: 62.2 years (22,709 days).
Specimen HCM-CSHL-0818-C56-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f36a341b-da3d-4e4a-8313-c97e0cc3b2d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0818-C56-10A (Blood Derived Normal), aliquot HCM-CSHL-0818-C56-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/643f2384-78c9-4eb4-ab1e-1e6db4f64c35

The open-access MAF lists 77 somatic variants for this specimen: 59 protein-altering or splice-affecting, 14 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 14, Nonsense Mutation 4, Frame Shift Del 4, Splice Site 2, Intron 2, 5'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD3 | c.1156G>A p.G386S | Missense Mutation (SNP) | VAF 55/278 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs766791159, COSV64642475; called by muse, mutect2, varscan2
- CACNA1E | c.3090T>G p.S1030R | Missense Mutation (SNP) | VAF 186/740 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.094); catalogued as rs746949281; called by muse, mutect2, varscan2
- CD79A | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 29/398 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as rs1202927044; called by muse, mutect2
- CFAP157 | c.1511T>C p.L504P | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1466731753, COSV58852350; called by muse, mutect2, varscan2
- CNTNAP1 | c.2668C>T p.R890* | Nonsense Mutation (SNP) | VAF 77/285 reads (27%) | catalogued as rs144659252, COSV99226269; called by muse, mutect2, varscan2
- COL11A2 | c.4978C>T p.R1660C (on ENST00000341947 / NM_080680.3; = p.R1553C on NM_080679.2) | Missense Mutation (SNP) | VAF 109/682 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs546841812; called by muse, mutect2, varscan2
- CROCC | c.1826C>T p.A609V | Missense Mutation (SNP) | VAF 106/425 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as rs759425058; called by muse, mutect2, varscan2
- EVPL | c.4109T>A p.V1370E | Missense Mutation (SNP) | VAF 97/486 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs751058801; called by muse, mutect2, varscan2
- EVX2 | c.950G>C p.R317P | Missense Mutation (SNP) | VAF 90/615 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1395678401; called by muse, mutect2, varscan2
- FAM135B | c.1093C>G p.Q365E | Missense Mutation (SNP) | VAF 62/720 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99427310; called by muse, mutect2
- FMN2 | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 158/866 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV100143999; called by muse, mutect2, varscan2
- GLI2 | c.2761C>T p.R921W (on ENST00000361492 / NM_001374353.1; = p.R938W on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/500 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs900449843; called by muse, mutect2, varscan2
- IFIT2 | c.121C>G p.R41G | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs543713702, COSV51080522; called by muse, mutect2, varscan2
- LCT | c.4364G>A p.R1455H | Missense Mutation (SNP) | VAF 75/505 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867715897, COSV51548135; called by muse, mutect2, varscan2
- LOXL3 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 102/564 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775264232, COSV104382391; called by muse, mutect2, varscan2
- LTN1 | c.1226T>C p.I409T | Missense Mutation (SNP) | VAF 52/317 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs750217371, COSV100797882; called by muse, mutect2, varscan2
- NCAM2 | c.326del p.L109Wfs*58 | Frame Shift Del (DEL) | VAF 42/324 reads (13%) | catalogued as COSV99523298; called by mutect2, pindel, varscan2
- NELL1 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 116/294 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.103); catalogued as rs780205351, COSV100121398; called by muse, mutect2, varscan2
- PDILT | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 71/382 reads (19%) | catalogued as rs139247719, COSV56700444; called by muse, mutect2, varscan2
- PPP1R3E | c.440C>G p.P147R | Missense Mutation (SNP) | VAF 18/421 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs903005677; called by muse, mutect2
- SUGP1 | c.1623C>G p.F541L | Missense Mutation (SNP) | VAF 155/371 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.489); catalogued as rs1312881404; called by muse, mutect2, varscan2
- ZBP1 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 63/247 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as rs201702091, COSV59061549; called by muse, mutect2
- ZFHX4 | c.9925G>A p.G3309S | Missense Mutation (SNP) | VAF 57/560 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs775658313; called by muse, mutect2, varscan2
- AC244197.3 | c.952C>A p.P318T | Missense Mutation (SNP) | VAF 95/367 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- CACNA1E | c.5776del p.V1926Ffs*4 | Frame Shift Del (DEL) | VAF 51/472 reads (11%) | called by mutect2, pindel, varscan2
- CCDC8 | c.997G>T p.D333Y | Missense Mutation (SNP) | VAF 119/644 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CDC5L | c.1574T>C p.I525T | Missense Mutation (SNP) | VAF 50/292 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CEACAM18 | c.438C>A p.S146R | Missense Mutation (SNP) | VAF 71/336 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CNGA3 | c.1507T>C p.F503L | Missense Mutation (SNP) | VAF 54/433 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- CPSF3 | c.1309G>T p.D437Y | Missense Mutation (SNP) | VAF 51/598 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2
- CRH | c.152C>G p.P51R | Missense Mutation (SNP) | VAF 122/886 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DCAF5 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 62/355 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- EPAS1 | c.875G>T p.S292I | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCRL3 | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 174/351 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- GLE1 | c.1313-1G>C p.X438_splice | Splice Site (SNP) | VAF 34/145 reads (23%) | called by muse, mutect2, varscan2
- GOLGA6L6 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 66/625 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- GRB14 | c.454T>G p.F152V | Missense Mutation (SNP) | VAF 85/436 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IQSEC2 | c.617G>A p.S206N | Missense Mutation (SNP) | VAF 107/566 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- LCE2D | c.280_281del p.S94* | Frame Shift Del (DEL) | VAF 170/692 reads (25%) | called by pindel, varscan2
- NEB | c.403-15_404del p.X135_splice | Splice Site (DEL) | VAF 56/342 reads (16%) | called by mutect2, pindel, varscan2
- NPAS1 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 80/334 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PQBP1 | c.224G>T p.W75L | Missense Mutation (SNP) | VAF 70/334 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRSS36 | c.947A>G p.E316G | Missense Mutation (SNP) | VAF 71/449 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRM | c.2987T>G p.M996R | Missense Mutation (SNP) | VAF 61/386 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RUNX1T1 | c.408del p.F136Lfs*9 (on ENST00000265814 / NM_001198628.1; = p.F109Lfs*9 on NM_004349.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 82/922 reads (9%) | called by mutect2, pindel
- RUSC1 | c.2198T>A p.L733* (on ENST00000368352 / NM_001105203.2; = p.L264* on NM_014328.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 58/449 reads (13%) | called by muse, mutect2, varscan2
- SETD1A | c.2518G>C p.A840P | Missense Mutation (SNP) | VAF 60/303 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SPAG1 | c.2564A>G p.Q855R | Missense Mutation (SNP) | VAF 49/570 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); called by muse, mutect2
- SRSF11 | c.1358dup p.E454Gfs*10 | Frame Shift Ins (INS) | VAF 275/531 reads (52%) | called by mutect2, pindel, varscan2
- SYNE1 | c.1399T>C p.Y467H (on ENST00000367255 / NM_182961.4; = p.Y474H on NM_033071.3) | Missense Mutation (SNP) | VAF 80/338 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYT11 | c.721G>C p.V241L | Missense Mutation (SNP) | VAF 77/549 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- TAF11L8 | c.295T>C p.S99P | Missense Mutation (SNP) | VAF 121/462 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- TBX15 | c.419G>A p.R140K (on ENST00000369429 / NM_001330677.2; = p.R34K on NM_152380.3) | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2
- TENM2 | c.8084T>G p.V2695G (on ENST00000518659 / NM_001122679.2; = p.V2456G on NM_001080428.3) | Missense Mutation (SNP) | VAF 131/488 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- TTC9 | c.242A>T p.H81L | Missense Mutation (SNP) | VAF 83/455 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- VCAN | c.8954G>T p.G2985V | Missense Mutation (SNP) | VAF 86/274 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- WDR47 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 27/257 reads (11%) | called by muse, mutect2, varscan2
- ZBTB33 | c.937C>A p.Q313K | Missense Mutation (SNP) | VAF 65/387 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ZSCAN20 | c.2914T>G p.S972A | Missense Mutation (SNP) | VAF 57/509 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- CILP2 | c.153G>A p.E51= | Silent (SNP) | VAF 71/333 reads (21%) | called by muse, mutect2, varscan2
- ITPR1 | c.1260C>T p.T420= (on ENST00000354582; = p.T405= on NM_002222.7) | Silent (SNP) | VAF 33/213 reads (15%) | called by muse, mutect2, varscan2
- MARF1 | c.4608C>T p.L1536= | Silent (SNP) | VAF 67/430 reads (16%) | catalogued as rs770662256; called by muse, mutect2, varscan2
- MYB | c.1563C>G p.P521= | Silent (SNP) | VAF 11/242 reads (5%) | called by muse, mutect2
- OMP | c.399C>A p.A133= | Silent (SNP) | VAF 84/422 reads (20%) | called by muse, varscan2
- PCDHGA12 | c.2235G>C p.G745= | Silent (SNP) | VAF 93/393 reads (24%) | catalogued as COSV52759301; called by muse, mutect2, varscan2
- PDE1C | c.2124A>G p.R708= | Silent (SNP) | VAF 20/188 reads (11%) | called by muse, mutect2
- PLEC | c.13260C>T p.I4420= (on ENST00000322810 / NM_201380.4; = p.I4310= on NM_000445.5) | Silent (SNP) | VAF 73/688 reads (11%) | catalogued as rs782370693; called by muse, mutect2, varscan2
- ROPN1 | c.459G>A p.S153= | Silent (SNP) | VAF 97/377 reads (26%) | catalogued as rs750341418; called by muse, mutect2, varscan2
- RTN4IP1 | c.267T>C p.N89= | Silent (SNP) | VAF 19/196 reads (10%) | called by muse, mutect2, varscan2
- SLC7A1 | c.1405T>C p.L469= | Silent (SNP) | VAF 74/411 reads (18%) | catalogued as rs761908044; called by muse, mutect2, varscan2
- SUGP1 | c.1836C>G p.L612= | Silent (SNP) | VAF 329/722 reads (46%) | called by muse, mutect2, varscan2
- TLX2 | c.147G>A p.A49= | Silent (SNP) | VAF 100/716 reads (14%) | catalogued as rs1462911981; called by muse, mutect2, varscan2
- ZEB2 | c.1728C>T p.N576= | Silent (SNP) | VAF 61/433 reads (14%) | catalogued as rs1041704975; called by muse, mutect2, varscan2
- MIR296 | chr20:58819171 C>A | 5'Flank (SNP) | VAF 61/295 reads (21%) | called by muse, mutect2, varscan2
- MIR296 | chr20:58819172 C>T | 5'Flank (SNP) | VAF 61/291 reads (21%) | called by muse, mutect2, varscan2
- SLC22A23 | c.1579+143G>C | Intron (SNP) | VAF 55/458 reads (12%) | called by muse, mutect2, varscan2
- SON | c.6657+230G>A | Intron (SNP) | VAF 62/413 reads (15%) | catalogued as rs185513323; called by muse, mutect2, varscan2
